Somatic mutation profile of tumor specimen 743c74e4-cd76-4f38-8cb4-3c9107 (aliquot 743c74e4-cd76-4f38-8cb4-3c9107_D6_1) from CPTAC case 09CO018, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIA.
Specimen 743c74e4-cd76-4f38-8cb4-3c9107: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8aead750-9e76-4608-94f9-ed1559825e4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 74c4f1df-e3a5-423f-983d-3a0f94 (Blood Derived Normal), aliquot 74c4f1df-e3a5-423f-983d-3a0f94_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3153f2e-2aa1-42d6-ac00-e4db4d0f92a1

The open-access MAF lists 157 somatic variants for this specimen: 112 protein-altering or splice-affecting, 30 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 30, Nonsense Mutation 12, Intron 6, 3'UTR 3, 5'UTR 3, RNA 2, 5'Flank 1, Splice Site 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED12 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 33/219 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199469669, COSV61329437, COSV61329567, COSV61330093; ClinVar: not provided; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 142/302 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PCBP1 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 90/259 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57850093, COSV57850258, COSV57850830; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 104/534 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 118/490 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ADAM20 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 21/283 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs529674678, COSV56454605; called by muse, mutect2
- AKAP8 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1272082169, COSV99511768; called by muse, mutect2
- ALMS1 | c.10421G>A p.R3474H | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757108070, COSV52502679, COSV52520228; called by muse, varscan2
- ANKFY1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs1323792936; called by muse, mutect2, varscan2
- AOC2 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 65/286 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs267604890, COSV53827971; called by muse, mutect2, varscan2
- APC | c.4108A>T p.K1370* | Nonsense Mutation (SNP) | VAF 122/281 reads (43%) | catalogued as CM920054, COSV57335316; called by muse, mutect2, varscan2
- ARHGAP6 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1265883808; called by muse, mutect2, varscan2
- ATIC | c.916G>C p.A306P | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV52691907; called by muse, mutect2, varscan2
- BOD1L1 | c.6590C>T p.A2197V | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs755143500, COSV50045089; called by muse, mutect2, varscan2
- BORA | c.460C>T p.Q154* (on ENST00000613797; = p.Q79* on NM_024808.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as rs899754147; called by muse, mutect2, varscan2
- C2CD4C | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as rs1020409139, COSV59966190; called by muse, mutect2
- CA3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759873251, COSV53410509; called by muse, mutect2, varscan2
- CAD | c.3142C>T p.R1048C | Missense Mutation (SNP) | VAF 96/561 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1372902996, COSV99254340; called by muse, mutect2, varscan2
- CEP170B | c.3530G>A p.R1177Q (on ENST00000453495; = p.R1106Q on NM_015005.3) | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757788364, COSV69023878; called by muse, mutect2, varscan2
- CLDN8 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54526209; called by muse, mutect2
- CNGB3 | c.2143G>T p.E715* | Nonsense Mutation (SNP) | VAF 38/209 reads (18%) | catalogued as rs1563711403, COSV100182459, COSV100182830; called by muse, mutect2, varscan2
- COL7A1 | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 58/809 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.397); catalogued as rs377140103; called by muse, mutect2
- CRYBB2 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 80/344 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as rs777455525, COSV101236754; called by muse, mutect2, varscan2
- DIDO1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs758688330; called by muse, mutect2, varscan2
- DPF2 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52890310; called by muse, mutect2, varscan2
- EFL1 | c.3026G>A p.R1009Q | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as rs187991095; called by muse, mutect2, varscan2
- ERBB3 | c.251C>A p.T84K | Missense Mutation (SNP) | VAF 83/213 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57250400; called by mutect2, varscan2
- EXOSC8 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776668552; called by muse, mutect2, varscan2
- FAM155A | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs753292869, COSV65573454; called by muse, mutect2
- FEZF2 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs750692736; called by muse, mutect2
- GALNT11 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs764568487; called by muse, mutect2, varscan2
- GEMIN5 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1209239200; called by muse, mutect2, varscan2
- GRIA1 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.029); catalogued as rs371725726; called by muse, mutect2, varscan2
- IKZF1 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 9/96 reads (9%) | catalogued as COSV58787350; called by muse, mutect2
- ITIH5 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.013); catalogued as rs776611832; called by muse, mutect2, varscan2
- JMJD4 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs911379275, COSV59918737; called by muse, mutect2, varscan2
- KIAA0232 | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 66/325 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV56923371; called by muse, mutect2, varscan2
- KLHL34 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 70/430 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.452); catalogued as rs376948597; called by muse, mutect2, varscan2
- KRTAP25-1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs748034464, COSV68914211, COSV68914396; called by muse, mutect2, varscan2
- LAMC3 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 168/739 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs751314241, COSV63094440; called by muse, mutect2, varscan2
- MAP4K3 | c.1832A>G p.N611S | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV55719014; called by muse, mutect2, varscan2
- MUC12 | c.8956G>A p.G2986S (on ENST00000379442; = p.G2843S on NM_001164462.1) | Missense Mutation (SNP) | VAF 52/1408 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as rs1455958295; called by muse, mutect2
- NBEA | c.2597G>A p.R866H | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs771386003; called by muse, mutect2, varscan2
- NPTN | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 48/385 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs759373275, COSV54739438; called by muse, mutect2, varscan2
- OPA1 | c.1294G>A p.V432I (on ENST00000361510 / NM_130837.3; = p.V377I on NM_015560.3) | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.895); catalogued as rs780922750, CM130779; called by muse, mutect2
- PCDHB8 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 68/346 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.751); catalogued as rs782235349, COSV50759260, COSV99175201; called by muse, mutect2, varscan2
- PCDHGA4 | c.2173G>A p.V725M | Missense Mutation (SNP) | VAF 79/412 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs375096659; called by muse, mutect2, varscan2
- PCDHGA6 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 190/567 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1415388106, COSV53989482; called by muse, mutect2, varscan2
- PEG3 | c.2780C>A p.S927* | Nonsense Mutation (SNP) | VAF 56/299 reads (19%) | catalogued as rs1339198889, COSV99063492, COSV99690633; called by muse, mutect2, varscan2
- PLIN5 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs371504399; called by muse, mutect2, varscan2
- PNPLA3 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs753393489, COSV53379961; called by muse, mutect2, varscan2
- PORCN | c.1094G>A p.R365Q (on ENST00000326194 / NM_203475.3; = p.R354Q on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/603 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM093035, COSV58226234; called by muse, mutect2, varscan2
- PRSS37 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.422); catalogued as rs758971042, COSV63340144; called by muse, mutect2, varscan2
- RBMXL3 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.097); catalogued as rs1363399345; called by muse, mutect2, varscan2
- RNF220 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs200720362; called by muse, mutect2, varscan2
- RPGRIP1 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs1217633462; called by muse, mutect2, varscan2
- RPS14 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV56316705; called by muse, mutect2, varscan2
- SCRT1 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as rs553794841, COSV59780679; called by muse, mutect2, varscan2
- SGCG | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs191040430, COSV54556779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIX6 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 58/270 reads (21%) | catalogued as COSV59801625; called by muse, mutect2, varscan2
- SLC35C1 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 239/679 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs748793953, COSV100029354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLFN5 | c.230A>T p.D77V | Missense Mutation (SNP) | VAF 73/309 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs1292111586; called by muse, mutect2, varscan2
- SNX19 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs374201205; called by muse, mutect2, varscan2
- SPTA1 | c.1053C>G p.S351R | Missense Mutation (SNP) | VAF 109/334 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV63748661; called by muse, mutect2, varscan2
- SYMPK | c.1381G>A p.G461R | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.607); catalogued as rs1466533013; called by muse, mutect2, varscan2
- TAS2R41 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs779872662, COSV68764906; called by muse, mutect2, varscan2
- THSD7A | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 104/436 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769058292, COSV70262329; called by muse, varscan2
- TICRR | c.5086G>A p.A1696T | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs745591491; called by muse, mutect2, varscan2
- TMEM151A | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.908); catalogued as rs564401899, COSV59174478; called by muse, mutect2, varscan2
- TRDJ3 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 37/155 reads (24%) | catalogued as rs562632544; called by muse, mutect2, varscan2
- TRIB2 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50223990; called by muse, mutect2, varscan2
- TRPM3 | c.4273G>A p.V1425M (on ENST00000357533 / NM_001366142.2; = p.V1280M on NM_020952.6) | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs757556760, COSV100678655; called by muse, mutect2, varscan2
- TUB | c.124C>T p.R42C (on ENST00000299506 / NM_177972.3; = p.R97C on NM_003320.4) | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs772509519; called by muse, mutect2, varscan2
- TUT7 | c.4265G>A p.R1422Q | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs201306794, COSV99462942, COSV99463141; called by muse, mutect2, varscan2
- WDFY4 | c.1462C>A p.Q488K | Missense Mutation (SNP) | VAF 66/351 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100300842; called by muse, mutect2, varscan2
- XYLT2 | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371946896; called by muse, mutect2, varscan2
- ZBTB11 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs747718261; called by muse, mutect2, varscan2
- ZIC4 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67172998; called by muse, mutect2, varscan2
- ZP1 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs145848014; called by muse, mutect2, varscan2
- ACTRT1 | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 63/389 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- APBB2 | c.1813G>A p.G605R (on ENST00000295974 / NM_001166050.2; = p.G606R on NM_004307.2) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF33 | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BMP2K | c.3266G>A p.S1089N | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BNC2 | c.3271A>C p.K1091Q | Missense Mutation (SNP) | VAF 153/467 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C12orf4 | c.607-1G>T p.X203_splice | Splice Site (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- C15orf39 | c.2174_2191del p.P725_A730del | In Frame Del (DEL) | VAF 59/358 reads (16%) | called by mutect2, pindel, varscan2
- CC2D2A | c.4806C>A p.Y1602* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- CTNNBL1 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2
- DNAH17 | c.13141G>A p.G4381R | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERBB4 | c.3689C>T p.P1230L | Missense Mutation (SNP) | VAF 96/642 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- GPR161 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRIK5 | c.1594A>G p.K532E | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- HOOK2 | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- IPP | c.637G>T p.G213* | Nonsense Mutation (SNP) | VAF 25/104 reads (24%) | called by muse, mutect2, varscan2
- ITGBL1 | c.869G>C p.G290A | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IVD | c.980G>T p.G327V (on ENST00000651168; = p.G324V on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 131/353 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KLF9 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 29/319 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MACROD2 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- MPV17L | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- NAV2 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.081); called by muse, varscan2
- NOD2 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 182/950 reads (19%) | called by mutect2, varscan2
- PABPC5 | c.920A>C p.K307T | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA3 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2
- PINK1 | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2
- RNASE1 | c.213dup p.N72Efs*68 | Frame Shift Ins (INS) | VAF 149/564 reads (26%) | called by mutect2, pindel, varscan2
- RNF32 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- ROCK2 | c.3590dup p.Y1197* | Nonsense Mutation (INS) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- RTL9 | c.3052C>G p.P1018A | Missense Mutation (SNP) | VAF 34/388 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); called by muse, mutect2
- SPATA31A6 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 67/517 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TLE4 | c.1521G>T p.K507N | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TRIM4 | c.749T>A p.I250N | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF99 | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ADCY3 | c.139C>T p.L47= | Silent (SNP) | VAF 54/361 reads (15%) | catalogued as rs748520021; called by muse, mutect2, varscan2
- CACNB3 | c.594G>A p.K198= | Silent (SNP) | VAF 43/242 reads (18%) | catalogued as rs1276674694; called by muse, mutect2, varscan2
- CCDC85A | c.984C>T p.H328= | Silent (SNP) | VAF 125/436 reads (29%) | catalogued as rs766118772, COSV68152936; called by muse, mutect2, varscan2
- CDHR3 | c.165G>T p.V55= | Silent (SNP) | VAF 26/482 reads (5%) | called by muse, mutect2
- CELSR1 | c.5094C>T p.S1698= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs764856914; called by muse, mutect2
- DPCD | c.123C>T p.D41= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as rs867341773; called by muse, mutect2, varscan2
- ELF4 | c.1215C>T p.H405= | Silent (SNP) | VAF 70/232 reads (30%) | called by muse, mutect2, varscan2
- FBH1 | c.3045C>G p.A1015= (on ENST00000362091 / NM_178150.3; = p.A1066= on NM_032807.4) | Silent (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
- GCKR | c.228C>T p.S76= | Silent (SNP) | VAF 82/259 reads (32%) | catalogued as rs371436300; called by muse, mutect2, varscan2
- GLIS1 | c.105G>A p.A35= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as rs777645960, COSV100389689; called by muse, mutect2, varscan2
- HAVCR2 | c.84G>A p.A28= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as rs767440273, COSV57152112; called by muse, mutect2, varscan2
- JAKMIP2 | c.369C>T p.D123= | Silent (SNP) | VAF 56/301 reads (19%) | catalogued as rs756380356, COSV54601804; called by muse, mutect2, varscan2
- JPH3 | c.63C>T p.D21= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as COSV99412669; called by muse, mutect2, varscan2
- KCNH4 | c.2289C>A p.G763= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs757101246, COSV52921493; called by muse, mutect2, varscan2
- KLHL34 | c.561C>T p.D187= | Silent (SNP) | VAF 24/470 reads (5%) | catalogued as COSV65278663; called by muse, mutect2
- LHCGR | c.60G>A p.P20= | Silent (SNP) | VAF 80/307 reads (26%) | called by mutect2, varscan2
- MAP2 | c.801C>T p.I267= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as rs775528286, COSV52288621; called by muse, mutect2, varscan2
- NATD1 | c.315G>A p.P105= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as rs544513896, COSV67541080; called by muse, mutect2, varscan2
- NBEAL2 | c.4845C>T p.R1615= | Silent (SNP) | VAF 56/170 reads (33%) | catalogued as rs750726027, COSV52762442; called by muse, mutect2, varscan2
- OBSCN | c.16161C>T p.S5387= | Silent (SNP) | VAF 30/224 reads (13%) | called by muse, mutect2, varscan2
- OMD | c.762C>T p.D254= | Silent (SNP) | VAF 33/148 reads (22%) | called by muse, mutect2, varscan2
- OR2D2 | c.864T>C p.Y288= | Silent (SNP) | VAF 76/185 reads (41%) | catalogued as rs1488793538, COSV100203729; called by muse, mutect2, varscan2
- PCDHA3 | c.72G>A p.S24= | Silent (SNP) | VAF 26/151 reads (17%) | catalogued as COSV65365647; called by muse, mutect2, varscan2
- PCSK5 | c.1350A>G p.E450= | Silent (SNP) | VAF 21/108 reads (19%) | called by muse, mutect2, varscan2
- PITRM1 | c.3030C>T p.G1010= | Silent (SNP) | VAF 38/283 reads (13%) | catalogued as rs755718688; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.42C>T p.S14= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs752856206, COSV59129942; called by muse, mutect2, varscan2
- TECPR2 | c.2265G>A p.E755= | Silent (SNP) | VAF 49/251 reads (20%) | called by muse, mutect2, varscan2
- TSHZ3 | c.2319G>A p.K773= | Silent (SNP) | VAF 24/202 reads (12%) | called by muse, mutect2, varscan2
- ZNF256 | c.966T>C p.P322= | Silent (SNP) | VAF 61/373 reads (16%) | called by muse, mutect2, varscan2
- ZNF423 | c.2682C>T p.Y894= (on ENST00000563137 / NM_001379286.1; = p.Y886= on NM_015069.4) | Silent (SNP) | VAF 60/363 reads (17%) | catalogued as rs763145316; called by muse, mutect2, varscan2
- ADAM12 | c.*7G>A | 3'UTR (SNP) | VAF 10/30 reads (33%) | catalogued as rs748056711; called by muse, mutect2, varscan2
- C16orf82 | c.-172A>C | 5'UTR (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2
- CAMK2G | c.1273+824G>T | Intron (SNP) | VAF 51/200 reads (26%) | called by muse, mutect2, varscan2
- CYYR1 | c.-194G>A | 5'UTR (SNP) | VAF 24/71 reads (34%) | catalogued as COSV54838841; called by muse, mutect2, varscan2
- LINC01001 | n.484G>C | RNA (SNP) | VAF 4/41 reads (10%) | catalogued as rs61869653; called by muse, mutect2
- NRXN1 | c.3719-1423T>G | Intron (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- PDPK2P | n.963C>T | RNA (SNP) | VAF 62/477 reads (13%) | catalogued as rs772072702; called by muse, mutect2, varscan2
- PNMA3 | c.*55A>G | 3'UTR (SNP) | VAF 29/257 reads (11%) | called by muse, mutect2, varscan2
- RAPGEF1 | c.1855-2983C>T | Intron (SNP) | VAF 32/155 reads (21%) | catalogued as rs757762524; called by muse, mutect2, varscan2
- RFTN1 | c.145+10912T>G | Intron (SNP) | VAF 36/263 reads (14%) | called by muse, mutect2, varscan2
- SSR4 | c.-19G>A | 5'UTR (SNP) | VAF 47/218 reads (22%) | called by muse, mutect2, varscan2
- TOR1A | c.444+143G>C | Intron (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- WNK1 | c.2140-2921C>T | Intron (SNP) | VAF 45/294 reads (15%) | catalogued as rs747566114, COSV100266016, COSV100266051; called by muse, mutect2, varscan2
- WT1 | chr11:32439186 G>A | 5'Flank (SNP) | VAF 79/226 reads (35%) | catalogued as rs778718883; called by muse, mutect2, varscan2
- WWOX | c.*7C>G | 3'UTR (SNP) | VAF 47/280 reads (17%) | called by muse, mutect2, varscan2
